CCDI case PBBZFI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3156df05-f49e-440d-a2ae-6a3669e3a448

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.8 years (3,581 days).

Biospecimens (3 samples)
- Sample 0DLPZB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLPZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLQ02: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
